Somatic mutation profile of tumor specimen TCGA-VP-A878-01A (aliquot TCGA-VP-A878-01A-31D-A34U-08) from TCGA case TCGA-VP-A878, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.6 years (21,402 days).
Specimen TCGA-VP-A878-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 266144f5-ec02-41bd-999b-2675a61bd34e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A878-10A (Blood Derived Normal), aliquot TCGA-VP-A878-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32a16cd2-82ca-4b3d-bef1-2674b906c269

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Frame Shift Del 3, Splice Site 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSF | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100839451; called by muse, varscan2
- ATPAF2 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100572658; called by muse, mutect2, varscan2
- ATRX | c.5760G>T p.M1920I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV100970273; called by muse, mutect2, varscan2
- BPHL | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100984444; called by muse, mutect2, varscan2
- CDH6 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV54067966; called by muse, mutect2, varscan2
- CHID1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100059533; called by muse, mutect2, varscan2
- COL1A2 | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as rs990076088, COSV99798977; called by muse, mutect2, varscan2
- DNAH9 | c.1123A>G p.N375D | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.139); catalogued as COSV52346057; called by muse, mutect2, varscan2
- DNTT | c.369C>A p.H123Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100960483; called by muse, mutect2, varscan2
- DPYD | c.2417T>C p.L806P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100928856; called by muse, mutect2, varscan2
- HMCN1 | c.12891C>A p.N4297K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99625888; called by muse, mutect2, varscan2
- IL6ST | c.1552+2T>G p.X518_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100410699; called by muse, mutect2, varscan2
- MYH8 | c.3952C>G p.L1318V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV101238309; called by muse, mutect2, varscan2
- OR5D13 | c.452A>T p.Y151F | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV100686772; called by muse, mutect2, varscan2
- PLCH2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771761811, COSV53939186; called by muse, mutect2, varscan2
- SLC26A3 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV100384913, COSV100385279; called by muse, mutect2, varscan2
- SPTA1 | c.5269C>T p.R1757C | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754598605, COSV63754961; called by muse, mutect2, varscan2
- STYXL1 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.021); catalogued as rs782406219, COSV50388816; called by muse, mutect2, varscan2
- TRRAP | c.2561A>G p.D854G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1554409717, COSV100722199; called by muse, mutect2, varscan2
- CSPP1 | c.281C>A p.A94D (on ENST00000676605; = p.A53D on NM_024790.6) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2E | c.2986_2987del p.K996Dfs*8 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- SPOP | c.116del p.N39Ifs*27 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | called by mutect2, pindel, varscan2
- ZMYND11 | c.912_915del p.N304Kfs*33 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
- AGPS | c.1881A>G p.L627= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV99931139; called by muse, mutect2, varscan2
- ARAP2 | c.3598C>T p.L1200= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100394290; called by muse, mutect2, varscan2
- CDC20 | c.1401G>A p.L467= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV100196370; called by muse, mutect2, varscan2
- DEF6 | c.180C>T p.D60= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs776898412, COSV57355140; called by muse, mutect2, varscan2
- PDE6D | c.276C>T p.F92= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs571686278, COSV55021320; called by muse, mutect2, varscan2
- PKD1 | c.4143C>T p.G1381= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99237487; called by muse, mutect2, varscan2
- TTC29 | c.1347C>T p.S449= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100283389; called by muse, mutect2
- TTN | c.9846C>T p.G3282= (on ENST00000591111; = p.G3236= on NM_003319.4) | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV100600643; called by muse, mutect2, varscan2
- ZNF70 | c.939C>T p.C313= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs372898022; called by muse, mutect2, varscan2
- ATG13 | c.*356A>G | 3'UTR (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100357835; called by muse, mutect2, varscan2
